Somatic mutation profile of tumor specimen TCGA-06-0137-01A (aliquot TCGA-06-0137-01A-01D-1490-08) from TCGA case TCGA-06-0137, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 63.7 years (23,273 days).
Specimen TCGA-06-0137-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 85e9d806-e394-44b5-afe9-93f7d17d17f5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-0137-10A (Blood Derived Normal), aliquot TCGA-06-0137-10A-01D-1490-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/768ad713-cad3-4fbf-84b6-41974aabb872

The open-access MAF lists 80 somatic variants for this specimen: 54 protein-altering or splice-affecting, 25 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, Silent 25, Nonsense Mutation 3, Frame Shift Del 2, Frame Shift Ins 1, RNA 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATL1 | c.715C>T p.R239C | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.286); catalogued as rs119476046, CM013290, COSV63296065; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- EGFR | c.1787C>T p.P596L | Missense Mutation (SNP) | VAF 157/2603 reads (6%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1477025000, COSV51779162, COSV51807036; called by muse, mutect2
- ABLIM3 | c.1939C>T p.R647C | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371092037; called by muse, mutect2, varscan2
- ACSM3 | c.232C>A p.P78T | Missense Mutation (SNP) | VAF 71/181 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.038); catalogued as COSV55501013; called by muse, mutect2, varscan2
- AGTR1 | c.418C>T p.R140C | Missense Mutation (SNP) | VAF 109/237 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763952495, COSV62557123; called by muse, mutect2, varscan2
- ATP6V0A4 | c.787G>A p.V263I | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.088); catalogued as rs781671157, COSV59474671; called by muse, mutect2, varscan2
- C1orf100 | c.19C>T p.R7* | Nonsense Mutation (SNP) | VAF 36/105 reads (34%) | catalogued as rs200838303; called by muse, mutect2, varscan2
- CD44 | c.1387C>T p.R463* | Nonsense Mutation (SNP) | VAF 70/161 reads (43%) | catalogued as rs749270293, COSV53528782; called by muse, mutect2, varscan2
- CDKL5 | c.2715C>T p.D905= | Splice Region (SNP) | VAF 26/94 reads (28%) | catalogued as rs201714912, COSV66106173; called by muse, mutect2, varscan2
- COL19A1 | c.1379A>G p.D460G | Missense Mutation (SNP) | VAF 30/56 reads (54%) | SIFT deleterious (0.03); PolyPhen benign (0.025); catalogued as COSV59570605; called by muse, mutect2, varscan2
- DAO | c.856C>T p.R286C | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768403852, COSV57321630; called by muse, mutect2, varscan2
- DIAPH2 | c.3224G>A p.R1075Q | Missense Mutation (SNP) | VAF 32/64 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs771338255, COSV100230461, COSV61266215; called by muse, mutect2, varscan2
- DOCK2 | c.508G>A p.G170R | Missense Mutation (SNP) | VAF 66/177 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56953545; called by muse, mutect2, varscan2
- EPHA6 | c.802C>T p.R268C | Missense Mutation (SNP) | VAF 198/426 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs750297483, COSV67556787; called by muse, mutect2, varscan2
- FCAMR | c.431G>A p.R144H | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374305028, COSV61367373; called by muse, mutect2, varscan2
- FCRL2 | c.542C>T p.T181M | Missense Mutation (SNP) | VAF 59/140 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.913); catalogued as rs756244463, COSV63833280; called by muse, mutect2, varscan2
- FOLR1 | c.374G>A p.R125H | Missense Mutation (SNP) | VAF 46/106 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs1202769307, CM1311252, COSV56615963; called by muse, mutect2, varscan2
- HCRTR2 | c.503G>A p.R168Q | Missense Mutation (SNP) | VAF 45/118 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs755365044, COSV63793832; called by muse, mutect2, varscan2
- IQCE | c.380G>A p.R127H | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.026); catalogued as rs199937900, COSV58077088, COSV58077743; called by muse, mutect2, varscan2
- KCNV1 | c.956C>A p.A319D | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.627); catalogued as COSV52085645; called by muse, mutect2, varscan2
- KIF2B | c.334G>A p.A112T | Missense Mutation (SNP) | VAF 76/182 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs753464095, COSV52127156; called by muse, mutect2, varscan2
- LRRC3 | c.680G>A p.R227H | Missense Mutation (SNP) | VAF 46/103 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs762873562, COSV52399135; called by muse, mutect2, varscan2
- LYPD4 | c.709G>A p.V237I | Missense Mutation (SNP) | VAF 53/215 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs375302712; called by muse, mutect2, varscan2
- MACF1 | c.88C>T p.R30W | Missense Mutation (SNP) | VAF 23/66 reads (35%) | catalogued as rs537793971, COSV58369393; called by muse, mutect2, varscan2
- MAGEA1 | c.511C>T p.L171F | Missense Mutation (SNP) | VAF 109/254 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.193); catalogued as COSV63118442; called by muse, mutect2, varscan2
- MYH6 | c.4723G>A p.E1575K | Missense Mutation (SNP) | VAF 161/351 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.544); catalogued as rs371067114; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NOS1 | c.208C>T p.R70W | Missense Mutation (SNP) | VAF 68/120 reads (57%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.851); catalogued as rs1362576199, COSV57610659; called by muse, mutect2, varscan2
- OR2T10 | c.635C>T p.T212M | Missense Mutation (SNP) | VAF 48/57 reads (84%) | SIFT deleterious (0.04); PolyPhen benign (0.063); catalogued as rs755113821, COSV57896648; called by muse, mutect2, varscan2
- OR4C16 | c.92G>A p.R31H | Missense Mutation (SNP) | VAF 89/223 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs374191202, COSV58941555; called by muse, mutect2, varscan2
- OR51F1 | c.222G>T p.R74S | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV58579370, COSV58580239; called by muse, mutect2
- PIK3C2G | c.2465G>A p.R822H (on ENST00000676171; = p.R781H on NM_004570.5) | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs765821860; called by muse, mutect2, varscan2
- PLCB2 | c.2626G>A p.E876K | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0.006); catalogued as COSV53032704; called by muse, mutect2, varscan2
- PRKCSH | c.1277G>A p.R426H | Missense Mutation (SNP) | VAF 88/275 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1009736502, COSV52951036; called by muse, mutect2, varscan2
- PSG7 | c.1087C>G p.Q363E | Missense Mutation (SNP) | VAF 21/553 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs751735611, COSV101343325; called by muse, mutect2
- RAI14 | c.1888A>G p.M630V | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.197); catalogued as COSV54292842; called by muse, mutect2, varscan2
- RBFOX1 | c.950G>A p.R317H | Missense Mutation (SNP) | VAF 46/111 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs776698363, COSV60952220; called by muse, mutect2, varscan2
- SCN10A | c.2449C>T p.R817* | Nonsense Mutation (SNP) | VAF 43/121 reads (36%) | catalogued as rs763084100, COSV71860285; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SGSM1 | c.928G>A p.V310I | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.557); catalogued as rs375323027; called by muse, mutect2
- SLC27A6 | c.391G>A p.V131M | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.879); catalogued as COSV52482232; called by muse, mutect2, varscan2
- SYN3 | c.1223G>A p.R408K | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV60506140; called by muse, mutect2, varscan2
- TENM1 | c.4732G>A p.A1578T | Missense Mutation (SNP) | VAF 47/101 reads (47%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as rs148440423, COSV64430092; called by muse, mutect2, varscan2
- TMEM156 | c.241C>T p.R81C | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as rs13118782; called by muse, mutect2, varscan2
- TMPRSS7 | c.1504C>T p.R502C (on ENST00000452346; = p.R376C on NM_001042575.2) | Missense Mutation (SNP) | VAF 28/447 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs775082233; called by muse, mutect2
- UGT3A2 | c.1406C>T p.T469M | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.436); catalogued as rs199567567; called by muse, mutect2, varscan2
- ZNF491 | c.239G>A p.R80H | Missense Mutation (SNP) | VAF 53/154 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs375933257; called by muse, mutect2, varscan2
- ABCD2 | c.880dup p.Y294Lfs*20 | Frame Shift Ins (INS) | VAF 80/245 reads (33%) | called by mutect2, pindel, varscan2
- IGHV3-64 | c.59G>A p.C20Y | Missense Mutation (SNP) | VAF 108/242 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- ITGAM | c.2682C>A p.N894K (on ENST00000648685 / NM_001145808.2; = p.N893K on NM_000632.4) | Missense Mutation (SNP) | VAF 107/291 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KIF4A | c.223G>T p.G75C | Missense Mutation (SNP) | VAF 4/78 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); called by muse, mutect2
- PCLO | c.3239del p.T1080Mfs*19 | Frame Shift Del (DEL) | VAF 9/29 reads (31%) | called by mutect2, pindel, varscan2
- PCNX2 | c.3934T>C p.F1312L | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.39); called by muse, mutect2, varscan2
- PTN | c.122A>T p.K41I | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- TLR6 | c.663del p.C222Afs*4 | Frame Shift Del (DEL) | VAF 33/106 reads (31%) | called by mutect2, pindel, varscan2
- ZNF292 | c.3944G>C p.G1315A | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.83); PolyPhen benign (0); called by muse, mutect2, varscan2
- ALG13 | c.135G>A p.T45= | Silent (SNP) | VAF 11/302 reads (4%) | catalogued as rs1480398287; called by muse, mutect2
- AMDHD1 | c.675C>T p.H225= | Silent (SNP) | VAF 55/118 reads (47%) | catalogued as rs1277558919, COSV57138342; called by muse, mutect2, varscan2
- CDH20 | c.225C>T p.T75= | Silent (SNP) | VAF 15/226 reads (7%) | catalogued as rs1446101100; called by muse, mutect2
- CELSR1 | c.3723C>T p.D1241= | Silent (SNP) | VAF 31/80 reads (39%) | catalogued as rs1448340497, COSV53088040, COSV53099642; called by muse, mutect2, varscan2
- CHST5 | c.192C>T p.H64= | Silent (SNP) | VAF 16/34 reads (47%) | catalogued as rs768713791, COSV60338601; called by muse, mutect2, varscan2
- CSMD3 | c.1197G>A p.T399= | Silent (SNP) | VAF 103/234 reads (44%) | catalogued as rs747304767, COSV52156062; called by muse, mutect2, varscan2
- DLGAP2 | c.1086C>T p.D362= | Silent (SNP) | VAF 16/45 reads (36%) | catalogued as rs758718171, COSV70099024; called by muse, mutect2, varscan2
- GABBR2 | c.948C>T p.G316= | Silent (SNP) | VAF 29/66 reads (44%) | catalogued as rs369085352; called by muse, mutect2, varscan2
- GTF2IRD2 | c.597G>A p.A199= | Silent (SNP) | VAF 10/70 reads (14%) | catalogued as rs782592175; called by mutect2, varscan2
- HSH2D | c.96C>T p.P32= | Silent (SNP) | VAF 38/112 reads (34%) | catalogued as rs77723805; called by muse, mutect2, varscan2
- ITGA4 | c.1233G>A p.S411= | Silent (SNP) | VAF 44/93 reads (47%) | catalogued as rs368002151; called by muse, mutect2, varscan2
- MAB21L3 | c.402C>T p.D134= | Silent (SNP) | VAF 40/107 reads (37%) | catalogued as rs781180790, COSV65673797; called by muse, mutect2, varscan2
- MTMR11 | c.1860A>G p.P620= (on ENST00000439741 / NM_001145862.2; = p.P548= on NM_181873.3) | Silent (SNP) | VAF 110/236 reads (47%) | catalogued as COSV54965090; called by muse, mutect2, varscan2
- NTRK1 | c.375C>T p.N125= | Silent (SNP) | VAF 49/139 reads (35%) | catalogued as rs757803799, COSV62323871; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- OGDH | c.2031C>T p.D677= | Silent (SNP) | VAF 37/92 reads (40%) | catalogued as rs781776901, COSV56045571; called by muse, mutect2, varscan2
- POLQ | c.2392C>A p.R798= | Silent (SNP) | VAF 23/64 reads (36%) | catalogued as rs753866746, COSV51748341, COSV51749862; called by muse, mutect2, varscan2
- RFX2 | c.1938C>T p.D646= | Silent (SNP) | VAF 23/90 reads (26%) | catalogued as rs774312384, COSV57940888; called by muse, mutect2, varscan2
- RPS6KA1 | c.1152C>T p.T384= | Silent (SNP) | VAF 37/85 reads (44%) | catalogued as rs745989127, COSV65175977; called by muse, mutect2, varscan2
- RRAD | c.429C>T p.Y143= | Silent (SNP) | VAF 99/250 reads (40%) | catalogued as rs745613040, COSV55336179; called by muse, mutect2, varscan2
- RRP36 | c.304C>A p.R102= | Silent (SNP) | VAF 50/122 reads (41%) | catalogued as COSV55064081; called by muse, mutect2, varscan2
- RTP2 | c.240C>T p.R80= | Silent (SNP) | VAF 20/44 reads (45%) | catalogued as rs1428483091, COSV64078743, COSV64079249; called by muse, mutect2, varscan2
- RYR3 | c.2121C>T p.D707= | Silent (SNP) | VAF 146/362 reads (40%) | catalogued as rs369220734; called by muse, mutect2, varscan2
- SCN5A | c.4980C>T p.I1660= (on ENST00000333535 / NM_198056.3; = p.I1659= on NM_000335.5) | Silent (SNP) | VAF 46/174 reads (26%) | catalogued as rs752079563, COSV61116484; ClinVar: likely benign; called by muse, mutect2, varscan2
- TSC1 | c.36C>A p.A12= | Silent (SNP) | VAF 38/147 reads (26%) | catalogued as COSV53766125; called by muse, mutect2, varscan2
- UTS2R | c.405C>T p.H135= | Silent (SNP) | VAF 28/52 reads (54%) | catalogued as rs1176939014, COSV100493406, COSV57452786; called by muse, mutect2, varscan2
- MIR758 | n.51G>A | RNA (SNP) | VAF 91/193 reads (47%) | catalogued as rs757142896; called by muse, mutect2, varscan2
